Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EL-01A (Primary Tumor).

[page 1 of 6]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site Code: Liver C22.0 1/19/11
lw

Patient Key:
Surgical date:

DIAGNOSIS:

A. Liver, segment III, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 0.8 x 0.7 x 0.7 cm mass. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.8 cm). There is no vascular space involvement. The histological features of the adjacent liver parenchyma will be reported in an addendum.

B. Gallbladder, cholecystectomy: Mild chronic cholecystitis. A single benign cystic duct lymph node is identified.

C. Liver, segments VII and VIII, resection: Grade 3 (of 4) hepatocellular carcinoma forming multiple (2) well-circumscribed masses (7.5 x 7.5 x 6.8 cm and 1.5 x 1.1 x 0.6 cm). There is no vascular space involvement.

ADDENDUM:

The adjacent liver parenchyma shows mild steatosis and mild portal lymphocytic infiltrates.

GROSS DESCRIPTION: A. Received fresh labeled "portion liver segment III" is a 3.56 gram, 2.5 x 2.1 x 1.6 cm partial hepatectomy specimen. A single 0.8 x 0.7 x 0.7 cm mass is present 0.8 from the surgical margin. Representative sections are submitted. B. Received fresh labeled "gallbladder" is a 7.2 x 3.0 x 1.5 cm gallbladder with a 0.2 maximum wall thickness and patent cystic duct. A cystic duct lymph node is identified. No stones are present within the lumen. No masses are identified. Cholesterosis is not identified. Representative sections are submitted.

C. Received fresh labeled "portion liver segment VII and VIII" is a 370.0 gram, 11.3 x 11.0 x 7.5 cm partial hepatectomy specimen. There are multiple (2) masses (7.5 x 7.5 x 6.8 cm and 1.5 x 1.1 x 0.6 cm) which are 1.1 cm from the closest resection margin. Representative sections are submitted.

BLOCK SUMMARY:

Part A: Portion liver segment 3
1 Liver Segment 3 mass

Part B: Gallbladder
1 Gallbladder
2 Cystic duct LN 1 (B1)

Part C: Portion liver segment 7 and 8

[page 2 of 6]
- 1 Liver segment 7/8 mass #1
- 2 Liver segment 7/8 mass #2
- 3 Uninvolved liver

[page 3 of 6]
Patient Key:
Surgical date:

DIAGNOSIS:

A. Liver, segment III, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 0.8 x 0.7 x 0.7 cm mass. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.8 cm). There is no vascular space involvement. The histological features of the adjacent liver parenchyma will be reported in an addendum.

B. Gallbladder, cholecystectomy: Mild chronic cholecystitis. A single benign cystic duct lymph node is identified.

C. Liver, segments VII and VIII, resection: Grade 3 (of 4) hepatocellular carcinoma forming multiple (2) well-circumscribed masses (7.5 x 7.5 x 6.8 cm and 1.5 x 1.1 x 0.6 cm). There is no vascular space involvement.

ADDENDUM:

The adjacent liver parenchyma shows mild steatosis and mild portal lymphocytic infiltrates.

GROSS DESCRIPTION: A. Received fresh labeled "portion liver segment III" is a 3.56 gram, 2.5 x 2.1 x 1.6 cm partial hepatectomy specimen. A single 0.8 x 0.7 x 0.7 cm mass is present 0.8 from the surgical margin. Representative sections are submitted. B. Received fresh labeled "gallbladder" is a 7.2 x 3.0 x 1.5 cm gallbladder with a 0.2 maximum wall thickness and patent cystic duct. A cystic duct lymph node is identified. No stones are present within the lumen. No masses are identified. Cholesterolosis is not identified. Representative sections are submitted. C. Received fresh labeled "portion liver segment VII and VIII" is a 370.0 gram, 11.3 x 11.0 x 7.5 cm partial hepatectomy specimen. There are multiple (2) masses (7.5 x 7.5 x 6.8 cm and 1.5 x 1.1 x 0.6 cm) which are 1.1 cm from the closest resection margin. Representative sections are submitted.

BLOCK SUMMARY:

Part A: Portion liver segment 3
1 Liver Segment 3 mass

Part B: Gallbladder
1 Gallbladder
2 Cystic duct LN 1 (B1)

Part C: Portion liver segment 7 and 8

[page 5 of 6]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: ResectionPatient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☐ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☒ Explanted liver
☒ Other (specify): Segmental resection
☐ Not specified

Focality

- ☐ Solitary (specify location): _____
☒ Multiple (specify location): seg II, III, IV

Tumor SizeGreatest dimension: 2.5 cm*Additional dimensions: 0.5 x 6.8 cm☐ Cannot be determined (see Comment)**MICROSCOPIC****Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☒ GII: Moderately differentiated
☒ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 6 of 6]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☐ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☒ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☒ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: 1, cystic duct wNumber involved: 0

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 8.0 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

- Specify margin: _____
☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
* ☐ Present
* ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type):
* ☒ Other (specify): mild steatosis, mild portal lymphocyte infiltrates

Source: NCI Genomic Data Commons file a0e44249-247b-42ec-ade2-8b82ac519cc8 (TCGA-DD-A1EL.C8A1098A-0717-4801-A3E5-C13C42C65936.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).